Somatic mutation profile of tumor specimen C3L-02392-01 (aliquot CPT0203250011) from CPTAC case C3L-02392, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.8 years (21,470 days).
Specimen C3L-02392-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15e2162f-9eb7-4387-9337-11b923c217d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02392-71 (Blood Derived Normal), aliquot CPT0203310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ebb0913-81de-40f7-bae4-1dee0d3f8271

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Intron 3, Frame Shift Ins 1, 5'Flank 1, RNA 1, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 67/324 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 194/508 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC131160.1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 101/468 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs1349160332, COSV57700157; called by muse, mutect2, varscan2
- ASTN2 | c.2350C>T p.R784W (on ENST00000313400 / NM_001365069.1; = p.R733W on NM_014010.5) | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs772547673; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs994323717; called by muse, mutect2, varscan2
- CAPN14 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.146); catalogued as rs752121613, COSV101294634; called by muse, mutect2, varscan2
- CCDC62 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.975); catalogued as rs749893773, COSV53435245; called by muse, mutect2, varscan2
- EMID1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs754293900; called by muse, mutect2, varscan2
- EPN1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs779941442, COSV50040610; called by muse, varscan2
- GABRG2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.835); catalogued as rs909915168; called by muse, mutect2, varscan2
- IL16 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | catalogued as rs758294731; called by mutect2, varscan2
- L3MBTL1 | c.115G>A p.A39T (on ENST00000418998 / NM_001377303.1; = p.A17T on NM_032107.5) | Missense Mutation (SNP) | VAF 100/478 reads (21%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.02); catalogued as rs1397260921, COSV64231124; called by muse, mutect2, varscan2
- NDST4 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1407918167, COSV52114321; called by muse, mutect2, varscan2
- RALGAPA2 | c.5545G>A p.E1849K | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as rs372896469; called by muse, mutect2, varscan2
- TOPAZ1 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs564499009; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as rs1170295579; called by muse, mutect2, varscan2
- XKRX | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 81/405 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV60707892; called by muse, mutect2, varscan2
- ARID1A | c.5091dup p.D1698* | Frame Shift Ins (INS) | VAF 62/287 reads (22%) | called by mutect2, pindel, varscan2
- CCDC40 | c.2006A>G p.K669R | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CT47B1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 159/702 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FKRP | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD19 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NAGS | c.1498T>A p.F500I | Missense Mutation (SNP) | VAF 137/637 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- OR56A5 | c.389G>T p.C130F | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PCDH9 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PELI1 | c.851T>A p.V284E | Missense Mutation (SNP) | VAF 107/435 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNMA1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG16 | c.775del p.Q259Kfs*4 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | called by mutect2, pindel, varscan2
- SYN3 | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TP73 | c.1790C>G p.P597R | Missense Mutation (SNP) | VAF 115/543 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMIZ2 | c.2270T>C p.F757S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF729 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2727G>A p.T909= | Silent (SNP) | VAF 74/395 reads (19%) | called by muse, mutect2, varscan2
- CDC14A | c.354C>A p.L118= | Silent (SNP) | VAF 65/358 reads (18%) | called by muse, mutect2, varscan2
- CFC1 | c.150G>T p.P50= | Silent (SNP) | VAF 53/518 reads (10%) | called by muse, mutect2
- CLCN4 | c.2043C>T p.P681= | Silent (SNP) | VAF 115/570 reads (20%) | catalogued as rs770044114, COSV66464950, COSV66467094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX53 | c.954G>A p.K318= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs750265276; called by muse, mutect2, varscan2
- FRMPD4 | c.579T>C p.T193= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2
- HSPA6 | c.1614G>A p.V538= | Silent (SNP) | VAF 76/310 reads (25%) | called by muse, mutect2, varscan2
- ID1 | c.279G>A p.E93= | Silent (SNP) | VAF 93/460 reads (20%) | called by muse, mutect2, varscan2
- ISX | c.324C>T p.D108= | Silent (SNP) | VAF 46/287 reads (16%) | catalogued as rs779368908; called by muse, mutect2, varscan2
- NRROS | c.363C>T p.Y121= | Silent (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
- OR5AC2 | c.771G>A p.L257= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100684278; called by muse, mutect2, varscan2
- SLC39A3 | c.669C>T p.A223= | Silent (SNP) | VAF 32/170 reads (19%) | called by muse, mutect2, varscan2
- ZNF106 | c.483C>T p.S161= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs149767675; called by muse, mutect2, varscan2
- ANKRD20A8P | n.1461G>A | RNA (SNP) | VAF 94/492 reads (19%) | catalogued as rs782254521; called by muse, mutect2, varscan2
- ANXA8 | c.-3G>T | 5'UTR (SNP) | VAF 173/774 reads (22%) | called by muse, varscan2
- DEPDC7 | c.73+506G>T | Intron (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- FHAD1 | c.4123-6084C>T | Intron (SNP) | VAF 6/90 reads (7%) | catalogued as rs1032288912; called by muse, mutect2
- NFU1 | chr2:69437498 G>A | 5'Flank (SNP) | VAF 74/364 reads (20%) | catalogued as rs764768943; called by muse, mutect2, varscan2
- TM6SF2 | c.297+13C>T | Intron (SNP) | VAF 50/252 reads (20%) | catalogued as rs370418517; called by muse, mutect2, varscan2
